Somatic mutation profile of tumor specimen TCGA-F7-A624-01A (aliquot TCGA-F7-A624-01A-22D-A30E-08) from TCGA case TCGA-F7-A624, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.0 years (26,667 days).
Specimen TCGA-F7-A624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd7e5948-1fa2-4c2d-a1a6-41e417ec0935.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A624-10A (Blood Derived Normal), aliquot TCGA-F7-A624-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff591403-2ffa-4fa8-b133-8e3113ce8fa4

The open-access MAF lists 3,594 somatic variants for this specimen: 2,658 protein-altering or splice-affecting, 864 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,160, Silent 864, Frame Shift Del 271, Nonsense Mutation 65, Frame Shift Ins 61, Splice Site 57, Intron 30, Splice Region 24, In Frame Del 17, RNA 16, 3'UTR 9, 5'Flank 9.

Variants (750 of 3,594; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4338del p.K1446Nfs*11 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as rs781126037; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARSA | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs74315473, CM139390, CM940106, COSV53350851; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 40/194 reads (21%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.1813del p.I605Yfs*9 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CLCNKB | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909133, CM970324, COSV65160252; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1502del p.P501Lfs*57 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | catalogued as rs1085307855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COX14 | c.81del p.Y28Tfs*83 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | catalogued as rs34028295, COSV58724413; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CREBBP | c.4291A>G p.I1431V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as rs1486941702, COSV99268958; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 21/88 reads (24%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CYP19A1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434536, CM950332, COSV53057248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYS | c.1211dup p.N404Kfs*3 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | catalogued as rs764163418; ClinVar: likely pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GJB4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs80358212, CM035047, COSV100258328, COSV58356373; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.13450C>T p.R4484* | Nonsense Mutation (SNP) | VAF 100/236 reads (42%) | catalogued as rs587783690, CM111921, COSV56434635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs1555610898, CS072271, COSV100646254; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 13/70 reads (19%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 28/51 reads (55%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2
- PRNP | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); catalogued as rs74315412, CM961149; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RAD50 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 32/157 reads (20%) | catalogued as rs772468452, COSV54749843, COSV99529486; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.11320dup p.A3774Gfs*37 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs768698639; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TUBGCP4 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV99538892; called by muse, mutect2, varscan2
- A1CF | c.1681A>G p.K561E (on ENST00000373993 / NM_138932.2; = p.K553E on NM_014576.4) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99255446; called by muse, mutect2, varscan2
- A2M | c.1442T>G p.I481S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100588509, COSV59385132; called by muse, mutect2, varscan2
- A2ML1 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100228615; called by muse, mutect2, varscan2
- AADAC | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99233128; called by muse, mutect2, varscan2
- AAGAB | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.776); catalogued as COSV99971804; called by muse, mutect2, varscan2
- AARS2 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as rs770902982, COSV99771290; called by muse, mutect2, varscan2
- AASDH | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV99220942; called by muse, mutect2
- AATF | c.1579A>G p.M527V | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779232104; called by muse, mutect2, varscan2
- ABCA1 | c.2848T>C p.F950L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); catalogued as COSV101036635; called by muse, mutect2, varscan2
- ABCA13 | c.7675T>C p.Y2559H | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV101446857; called by muse, mutect2, varscan2
- ABCA13 | c.7837G>A p.D2613N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV101446858; called by muse, mutect2, varscan2
- ABCA13 | c.12562T>C p.Y4188H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1242464731, COSV101446859; called by muse, mutect2, varscan2
- ABCA9 | c.1200A>G p.I400M | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as COSV100382756; called by muse, mutect2
- ABCB11 | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 33/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99791678; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC9 | c.2342A>G p.Y781C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684865; called by muse, mutect2, varscan2
- ABCD1 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV99497317; called by muse, mutect2, varscan2
- ABCE1 | c.566A>C p.D189A | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99668438; called by muse, mutect2, varscan2
- ABCE1 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99668441; called by muse, mutect2, varscan2
- ABCG8 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177528099, COSV99699505; called by muse, mutect2, varscan2
- ABHD1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 32/132 reads (24%) | catalogued as COSV99574349; called by muse, mutect2, varscan2
- ABHD16B | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV99410550; called by muse, varscan2
- ABHD16B | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99410553; called by muse, varscan2
- ABHD4 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202089812, COSV53529534; called by muse, mutect2, varscan2
- ABHD8 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99917152; called by muse, mutect2, varscan2
- ABHD8 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV53112833; called by muse, mutect2
- ABL1 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100583579; called by muse, mutect2, varscan2
- ABL1 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100583580; called by muse, mutect2, varscan2
- ABLIM1 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771771385, COSV99521585; called by muse, mutect2, varscan2
- AC006059.2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV100045260; called by muse, mutect2, varscan2
- AC009779.3 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99221164; called by muse, mutect2, varscan2
- AC013489.1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as rs762443912, COSV99183836; called by muse, mutect2, varscan2
- AC131160.1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV100226117; called by muse, mutect2, varscan2
- ACACB | c.4516C>T p.R1506C | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs752832246, COSV100622457; called by muse, mutect2, varscan2
- ACAD10 | c.1938T>A p.H646Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100563890; called by muse, mutect2, varscan2
- ACAD11 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as COSV99391694; called by muse, mutect2, varscan2
- ACADL | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99284584; called by muse, mutect2, varscan2
- ACBD3 | c.1305G>C p.W435C | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100830921; called by muse, mutect2, varscan2
- ACCS | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV99772708; called by muse, mutect2, varscan2
- ACD | c.1484G>A p.R495H (on ENST00000620338; = p.R406H on NM_022914.3) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs374742891, COSV54669085; called by muse, mutect2, varscan2
- ACER3 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99568026; called by muse, mutect2, varscan2
- ACOT9 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321222; called by muse, mutect2, varscan2
- ACSF3 | c.1178A>G p.N393S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV100441149; called by muse, mutect2
- ACSM2A | c.803A>G p.N268S (on ENST00000219054; = p.N189S on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs759527974, COSV99524979; called by muse, mutect2, varscan2
- ACTL6B | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV99355468; called by muse, mutect2, varscan2
- ACTL8 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100958528; called by muse, mutect2, varscan2
- ACTN2 | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100856596; called by muse, mutect2, varscan2
- ACTRT1 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1325295425, COSV100947514; called by muse, mutect2, varscan2
- ADAD1 | c.172+2T>C p.X58_splice | Splice Site (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99635216; called by muse, mutect2, varscan2
- ADAD1 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1414912763, COSV99635218; called by muse, mutect2
- ADAM19 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs1307114017, COSV57439376; called by muse, mutect2, varscan2
- ADAM23 | c.2266A>G p.T756A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100006965; called by muse, mutect2, varscan2
- ADAM28 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs1217814867, COSV99738018; called by muse, mutect2, varscan2
- ADAM30 | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101023780; called by muse, mutect2, varscan2
- ADAM32 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454858168, COSV101165292; called by muse, mutect2, varscan2
- ADAMTS15 | c.2275T>C p.Y759H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143158; called by muse, mutect2
- ADAMTS19 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99176546; called by muse, mutect2, varscan2
- ADAMTS9 | c.5539G>A p.A1847T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99898912; called by muse, mutect2, varscan2
- ADCY7 | c.1041C>A p.C347* | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99575749; called by muse, mutect2, varscan2
- ADCY7 | c.2710T>C p.C904R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575751; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs769239511, COSV100416272; called by muse, mutect2, varscan2
- ADD1 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53268556; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs948715025, COSV99293016; called by muse, mutect2, varscan2
- ADGRB3 | c.3250A>G p.T1084A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.322); catalogued as COSV53256615; called by muse, mutect2
- ADGRB3 | c.3887T>C p.I1296T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1489688044, COSV99483971; called by muse, mutect2, varscan2
- ADGRD1 | c.1895G>A p.C632Y | Missense Mutation (SNP) | VAF 163/453 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55443341; called by muse, mutect2, varscan2
- ADGRE5 | c.1559A>G p.N520S (on ENST00000242786 / NM_078481.4; = p.N427S on NM_001784.5) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99660187; called by muse, mutect2, varscan2
- ADGRE5 | c.1943A>C p.Q648P (on ENST00000242786 / NM_078481.4; = p.Q555P on NM_001784.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99660188; called by muse, mutect2
- ADGRG4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV99794671; called by muse, mutect2, varscan2
- ADGRV1 | c.6427A>G p.T2143A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101315585; called by muse, mutect2
- ADGRV1 | c.7644G>A p.M2548I | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67988752; called by muse, mutect2, varscan2
- ADGRV1 | c.9755T>C p.M3252T | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101315587; called by muse, mutect2, varscan2
- ADORA2B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs780529349, COSV58482827, COSV58483558; called by muse, mutect2, varscan2
- ADRA2C | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215298465; called by muse, mutect2
- AFAP1 | c.1531-1G>T p.X511_splice | Splice Site (SNP) | VAF 13/144 reads (9%) | catalogued as COSV100631233; called by muse, mutect2
- AFDN | c.4994G>A p.R1665H (on ENST00000447894 / NM_001366320.1; = p.R1648H on NM_001207008.1) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1008853384, COSV100652624; called by muse, mutect2
- AGAP2 | c.1975G>A p.E659K (on ENST00000547588 / NM_001122772.2; = p.E323K on NM_014770.4) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs772641164, COSV57728061; called by muse, mutect2, varscan2
- AGBL1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs763415157, COSV69800923; called by muse, mutect2, varscan2
- AGBL1 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV101222341; called by muse, mutect2, varscan2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 44/209 reads (21%) | catalogued as rs1310675921; called by mutect2, pindel, varscan2
- AGO2 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048012; called by muse, mutect2, varscan2
- AGO4 | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100942807; called by muse, mutect2, varscan2
- AGRN | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs763762094, COSV65071772; called by muse, varscan2
- AGTRAP | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1318281460, COSV100065211; called by muse, mutect2, varscan2
- AGXT2 | c.581+2T>C p.X194_splice | Splice Site (SNP) | VAF 28/154 reads (18%) | catalogued as COSV99183719; called by muse, mutect2, varscan2
- AHCTF1 | c.3840G>T p.G1280= (on ENST00000366508; = p.G1254= on NM_015446.5) | Splice Region (SNP) | VAF 7/48 reads (15%) | catalogued as COSV58250911; called by muse, mutect2, varscan2
- AHCYL2 | c.1675A>G p.K559E | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.754); catalogued as COSV100273053, COSV61486761; called by muse, mutect2, varscan2
- AHDC1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99898984; called by muse, varscan2
- AHDC1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1266598825, COSV99898986; called by muse, varscan2
- AHNAK | c.10229T>C p.I3410T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99946085; called by muse, mutect2, varscan2
- AKAP10 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99855302; called by muse, mutect2, varscan2
- AKAP12 | c.4199T>C p.L1400P | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99482702; called by muse, mutect2, varscan2
- AKAP6 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV99799051; called by muse, mutect2, varscan2
- AKAP9 | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100662063; called by muse, mutect2, varscan2
- AKNA | c.1883C>A p.S628Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99799850; called by muse, mutect2, varscan2
- AKR1C1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1471636426, COSV101080393; called by muse, mutect2, varscan2
- AKR1C4 | c.126A>G p.I42M | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99578537; called by muse, mutect2, varscan2
- ALAS2 | c.1226T>C p.M409T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100238075; called by muse, mutect2, varscan2
- ALDH1A2 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99990489; called by muse, mutect2, varscan2
- ALDH3A1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855763; called by muse, mutect2, varscan2
- ALG6 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99673052; called by muse, mutect2, varscan2
- ALK | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs750194005, COSV66583891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALLC | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as COSV99377604, COSV99378251; called by muse, mutect2, varscan2
- ALPG | c.1423A>T p.T475S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV99779210; called by muse, mutect2, varscan2
- ALPK1 | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99453314; called by muse, mutect2, varscan2
- ALPK3 | c.3809T>C p.L1270P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as COSV99360382; called by muse, mutect2
- ALS2 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99968911; called by mutect2, varscan2
- ALS2CL | c.1627-2A>G p.X543_splice | Splice Site (SNP) | VAF 26/81 reads (32%) | catalogued as COSV59671474; called by muse, mutect2, varscan2
- ALX4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200419726, COSV61326530; called by muse, mutect2, varscan2
- AMFR | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99315686; called by muse, mutect2, varscan2
- ANGPT1 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99862171; called by muse, mutect2, varscan2
- ANK1 | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99224318; called by muse, mutect2, varscan2
- ANK2 | c.11660A>G p.Y3887C | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100000214; called by muse, varscan2
- ANK3 | c.2707A>G p.M903V (on ENST00000280772 / NM_001320874.2; = p.M37V on NM_001149.3) | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs947259563, COSV99778769; called by muse, mutect2, varscan2
- ANKFY1 | c.1856T>C p.M619T | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs755051926, COSV100492343; called by muse, mutect2, varscan2
- ANKHD1 | c.7585T>C p.W2529R | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99782371; called by muse, mutect2, varscan2
- ANKIB1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1442551125, COSV99728560; called by muse, mutect2
- ANKRD11 | c.6551C>T p.A2184V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99968550; called by muse, mutect2, varscan2
- ANKRD26 | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV101062994; called by muse, mutect2, varscan2
- ANKRD33 | c.266C>T p.A89V (on ENST00000340970 / NM_001304459.2; = p.A214V on NM_182608.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100001148; called by muse, mutect2, varscan2
- ANO2 | c.227C>A p.P76H (on ENST00000356134 / NM_001278597.3; = p.P80H on NM_001278596.3) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.416); catalogued as COSV100500047; called by muse, mutect2, varscan2
- ANO9 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as COSV100240801; called by muse, mutect2, varscan2
- ANP32E | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100029591; called by muse, mutect2, varscan2
- ANXA2R | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100148624; called by muse, mutect2, varscan2
- AOX1 | c.3821T>A p.F1274Y | Missense Mutation (SNP) | VAF 97/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99613436; called by muse, mutect2, varscan2
- AP002512.3 | c.1192A>T p.K398* | Nonsense Mutation (SNP) | VAF 6/103 reads (6%) | catalogued as COSV99687803; called by muse, mutect2
- AP002748.5 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100567744; called by muse, mutect2, varscan2
- AP1S1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454605128, COSV61760907; called by muse, mutect2, varscan2
- AP2B1 | c.1048A>G p.N350D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99250949; called by muse, varscan2
- AP4B1 | c.1284G>C p.E428D | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV99870625; called by muse, mutect2, varscan2
- AP5M1 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99841082; called by muse, mutect2, varscan2
- APC | c.3631A>G p.M1211V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs780084585, CD994307, CM1010211, COSV99965957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.6049A>G p.T2017A | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as CD106478, COSV99965960; called by muse, mutect2, varscan2
- APEH | c.1531del p.H511Ifs*24 | Frame Shift Del (DEL) | VAF 37/210 reads (18%) | catalogued as COSV56535366; called by mutect2, pindel, varscan2
- APOB | c.2978A>G p.Y993C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs762080553, COSV99264187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APPBP2 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV99319513; called by muse, mutect2, varscan2
- AREL1 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 37/803 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as rs755959741, COSV100707579; called by muse, mutect2
- ARFGEF1 | c.5153A>G p.N1718S | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763363183, COSV99141329; called by muse, mutect2, varscan2
- ARFGEF1 | c.1576T>C p.F526L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51616550; called by muse, mutect2
- ARFGEF2 | c.4559C>G p.S1520C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV100904087; called by muse, mutect2, varscan2
- ARFGEF3 | c.1982A>G p.K661R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99292663; called by muse, mutect2, varscan2
- ARHGAP1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100357821; called by muse, mutect2, varscan2
- ARHGAP17 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434923038, COSV99253012; called by muse, mutect2, varscan2
- ARHGAP27 | c.2014C>T p.R672C (on ENST00000428638 / NM_001282290.1; = p.R331C on NM_199282.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs531423719, COSV100976462, COSV100976504; called by muse, mutect2
- ARHGAP29 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53108597, COSV99557758; called by muse, mutect2
- ARHGAP30 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100920155; called by muse, mutect2, varscan2
- ARHGAP32 | c.2056G>C p.E686Q (on ENST00000310343 / NM_001378025.1; = p.E337Q on NM_014715.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100087159; called by muse, mutect2, varscan2
- ARHGAP33 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as COSV99137671; called by muse, mutect2, varscan2
- ARHGAP39 | c.3002A>G p.H1001R (on ENST00000276826 / NM_001308208.2; = p.H1032R on NM_025251.2) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52772055, COSV99430461; called by muse, mutect2, varscan2
- ARHGAP39 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs774423765, COSV99430471; called by muse, mutect2, varscan2
- ARHGAP6 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100497402; called by muse, mutect2, varscan2
- ARHGEF10 | c.364A>G p.T122A (on ENST00000398564; = p.T98A on NM_014629.4) | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV100034087; called by muse, mutect2
- ARHGEF12 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100754725; called by muse, mutect2, varscan2
- ARHGEF19 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs576557883, COSV54615299; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 15/149 reads (10%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF9 | c.927C>T p.G309= | Splice Region (SNP) | VAF 24/50 reads (48%) | catalogued as rs141158169, COSV53642959; called by muse, mutect2, varscan2
- ARID4A | c.2561A>C p.K854T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100794083; called by muse, mutect2, varscan2
- ARNT | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV99648570; called by muse, mutect2, varscan2
- ARPP21 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs766229611, COSV99491275; called by muse, mutect2, varscan2
- ARSI | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV100155908; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ARVCF | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs377012111; called by muse, mutect2, varscan2
- AS3MT | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100185603; called by muse, mutect2, varscan2
- ASAP2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV99855896; called by muse, mutect2, varscan2
- ASAP2 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV55637484; called by muse, mutect2, varscan2
- ASB10 | c.1063A>G p.N355D (on ENST00000420175 / NM_001142459.2; = p.N340D on NM_080871.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99318306; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs749460467; called by mutect2, varscan2
- ASB2 | c.1534C>A p.L512I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100279244; called by muse, mutect2
- ASB4 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99987117; called by muse, mutect2, varscan2
- ASB8 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100402298; called by muse, mutect2, varscan2
- ASCC2 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747619020, COSV100316083; called by muse, mutect2, varscan2
- ASF1B | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV99654240; called by muse, mutect2, varscan2
- ASH1L | c.8065C>T p.R2689* (on ENST00000368346 / NM_001366177.2; = p.R2684* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100853198; called by muse, mutect2, varscan2
- ASH1L | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs755792596, COSV64207562; called by muse, mutect2, varscan2
- ASH2L | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV99166938; called by muse, mutect2, varscan2
- ASPG | c.961T>A p.S321T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.19); catalogued as COSV101496356; called by muse, mutect2, varscan2
- ASPH | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs111708484; called by mutect2, varscan2
- ASPHD2 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV99313162; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by mutect2, varscan2
- ASTE1 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV99393679; called by muse, mutect2, varscan2
- ASXL2 | c.1931T>C p.V644A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99710451; called by muse, mutect2, varscan2
- ATAD2 | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs928149599, COSV99784224; called by muse, mutect2, varscan2
- ATAD2B | c.2540T>C p.V847A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99477128; called by muse, mutect2, varscan2
- ATAD3A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs552002436, COSV100186156; called by muse, mutect2, varscan2
- ATAD3C | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100426321; called by muse, mutect2, varscan2
- ATG2B | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.152); catalogued as rs1456141131, COSV99951964; called by muse, mutect2, varscan2
- ATM | c.8794G>A p.E2932K | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1240328733, COSV99587950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.319A>G p.S107G | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV100755700; called by muse, mutect2, varscan2
- ATP10A | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100790985; called by muse, mutect2, varscan2
- ATP1A2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100767676; called by muse, mutect2, varscan2
- ATP1A2 | c.1178A>T p.N393I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100767677; called by muse, mutect2, varscan2
- ATP1B2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as rs761002067, COSV51515939; called by muse, mutect2, varscan2
- ATP1B3 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99657180; called by muse, varscan2
- ATP2A1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59466175; called by muse, mutect2, varscan2
- ATP2A2 | c.2608-2A>G p.X870_splice | Splice Site (SNP) | VAF 54/266 reads (20%) | catalogued as COSV100428452; called by muse, mutect2, varscan2
- ATP2A3 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766610781, COSV59229181; called by muse, mutect2
- ATP2B1 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99665299; called by muse, mutect2, varscan2
- ATP5F1B | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100008028; called by muse, varscan2
- ATP6AP1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100870657; called by muse, mutect2, varscan2
- ATP6V0A1 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99230599; called by muse, mutect2, varscan2
- ATP6V0D1 | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99340978; called by muse, mutect2, varscan2
- ATP6V1A | c.797A>T p.Y266F | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV99849921; called by muse, mutect2, varscan2
- ATP6V1B1 | c.15A>G p.I5M | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV99313332; called by muse, mutect2
- ATP6V1B2 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99369277; called by muse, mutect2, varscan2
- ATP6V1E1 | c.33+2T>C p.X11_splice | Splice Site (SNP) | VAF 56/354 reads (16%) | catalogued as COSV99494222; called by muse, mutect2, varscan2
- ATP8A1 | c.1503T>A p.Y501* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100045308; called by muse, mutect2
- ATP8B3 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.056); catalogued as rs1245348893, COSV100034151; called by muse, mutect2
- ATP9A | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.05); catalogued as COSV100124474; called by muse, mutect2, varscan2
- ATXN1 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99785466; called by muse, mutect2, varscan2
- ATXN10 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99426099; called by muse, mutect2
- ATXN2L | c.2302A>G p.M768V | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV100293908; called by muse, varscan2
- ATXN7L3 | c.863C>G p.S288C (on ENST00000389384 / NM_001382309.1; = p.S295C on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100116055; called by muse, mutect2, varscan2
- AVPR1B | c.959T>C p.F320S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100899331, COSV65638372; called by muse, mutect2, varscan2
- AXIN1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759464398, COSV99249418, COSV99250343; called by muse, mutect2, varscan2
- B3GALT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs866876110, COSV59909329; called by muse, mutect2, varscan2
- B3GALT6 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as rs749438460, COSV99767409, COSV99767527; called by muse, mutect2
- B3GNT8 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99524464; called by muse, mutect2, varscan2
- B4GALNT3 | c.2621T>A p.I874N | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842595; called by muse, mutect2, varscan2
- B4GALT5 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100866941; called by muse, mutect2, varscan2
- BACH2 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as COSV99998393; called by muse, mutect2, varscan2
- BAG1 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV101116668; called by muse, mutect2, varscan2
- BAG3 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100958190; called by muse, varscan2
- BAG4 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV54861378; called by muse, mutect2, varscan2
- BAG5 | c.159A>G p.I53M | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99914695; called by muse, mutect2, varscan2
- BAHCC1 | c.5978A>G p.Y1993C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100311256; called by muse, mutect2
- BANK1 | c.2077T>A p.S693T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.941); catalogued as COSV100535970; called by muse, mutect2, varscan2
- BANP | c.787G>A p.E263K (on ENST00000286122; = p.E232K on NM_017869.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99620967; called by muse, mutect2
- BBS10 | c.344C>G p.T115S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99674645; called by muse, mutect2, varscan2
- BBS2 | c.1958A>T p.D653V | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs754870847, COSV99802184; called by muse, mutect2, varscan2
- BCL2L13 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100456186; called by muse, mutect2, varscan2
- BCL3 | c.856A>G p.N286D | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs1328677316, COSV99378006; called by muse, mutect2
- BCL6 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99215460; called by muse, mutect2, varscan2
- BCL9L | c.1442del p.G481Afs*21 | Frame Shift Del (DEL) | VAF 56/243 reads (23%) | catalogued as COSV52685994; called by mutect2, pindel, varscan2
- BDKRB2 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.02); catalogued as COSV100020946; called by muse, mutect2, varscan2
- BEST3 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58304628; called by muse, mutect2, varscan2
- BHLHE22 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100417644; called by muse, mutect2, varscan2
- BICD2 | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.059); catalogued as COSV100794017; called by muse, mutect2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs755506199; called by mutect2, varscan2
- BID | c.253G>A p.A85T (on ENST00000317361 / NM_197966.2; = p.A39T on NM_001196.4) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs372024838; called by muse, mutect2, varscan2
- BIRC6 | c.2383A>C p.N795H | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV101427966; called by muse, mutect2, varscan2
- BLM | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV100757033; called by muse, mutect2, varscan2
- BMERB1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405481702, COSV100252723; called by muse, mutect2, varscan2
- BMP10 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1372582750, COSV99770310; called by muse, mutect2, varscan2
- BMP2 | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1188623371, COSV101122061; called by muse, mutect2, varscan2
- BMP5 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1470292463, COSV100895809; called by muse, mutect2
- BMP8B | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as rs755566163, COSV100560209; called by mutect2, varscan2
- BMPR2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV101001319; called by muse, mutect2, varscan2
- BOD1L1 | c.2926A>G p.T976A | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99238633; called by muse, mutect2
- BORA | c.736G>A p.G246S (on ENST00000613797; = p.G171S on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100909650; called by muse, mutect2, varscan2
- BPTF | c.6638G>T p.G2213V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100074319; called by muse, mutect2, varscan2
- BRAF | c.1162T>C p.F388L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99953768; called by muse, mutect2, varscan2
- BRAF | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99953770; called by muse, mutect2, varscan2
- BRCC3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1557293751, COSV100341481; called by muse, mutect2, varscan2
- BRD3 | c.1415C>G p.A472G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100324755; called by muse, mutect2
- BRD3 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100324758; called by muse, mutect2, varscan2
- BRDT | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100740301; called by muse, mutect2, varscan2
- BRMS1 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV100254411, COSV100254744; called by muse, mutect2, varscan2
- BRPF1 | c.1722+2T>C p.X574_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100121132; called by muse, mutect2, varscan2
- BRWD1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV100313008; called by muse, mutect2, varscan2
- BSG | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs772713478, COSV100344535, COSV100344789; called by muse, mutect2, varscan2
- BSN | c.7506G>C p.W2502C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99607568; called by muse, mutect2, varscan2
- BTBD2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99724589; called by muse, mutect2, varscan2
- BTBD7 | c.2204T>C p.V735A | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV100597584; called by muse, mutect2, varscan2
- BTBD9 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV100021182; called by muse, mutect2, varscan2
- BUD13 | c.1699A>G p.S567G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs746050926, COSV99496310; called by muse, mutect2, varscan2
- C11orf24 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as rs750856609, COSV100422510; called by muse, mutect2, varscan2
- C11orf68 | c.487C>T p.R163C (on ENST00000530188; = p.R204C on NM_031450.4) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); catalogued as rs771333855, COSV100437056; called by muse, mutect2, varscan2
- C14orf28 | c.244_245del p.L82Sfs*4 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as rs746382141; called by pindel, varscan2
- C15orf39 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1031593823, COSV100641221; called by muse, mutect2, varscan2
- C1QTNF4 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV100209217; called by muse, mutect2, varscan2
- C1QTNF7 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs760065898, COSV99765052; called by muse, mutect2, varscan2
- C1orf112 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99609503; called by muse, mutect2, varscan2
- C1orf131 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as rs751437541, COSV100009587; called by muse, mutect2
- C1orf56 | c.997A>T p.M333L | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV99764552; called by muse, mutect2, varscan2
- C2CD5 | c.2145A>G p.I715M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.854); catalogued as rs1320151915, COSV100448542; called by muse, mutect2
- C2orf16 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101284348; called by muse, varscan2
- C3orf14 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99223695; called by muse, mutect2, varscan2
- C3orf62 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV99649105; called by muse, mutect2, varscan2
- C3orf62 | c.55_57del p.R19del | In Frame Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs751827513; called by pindel, varscan2
- C9 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV99661814; called by muse, mutect2, varscan2
- CABIN1 | c.2836T>C p.C946R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99572822; called by muse, mutect2, varscan2
- CABIN1 | c.5609G>A p.G1870D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1311704305, COSV99572825; called by muse, mutect2, varscan2
- CACHD1 | c.2560A>G p.I854V | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV99261680; called by muse, mutect2
- CACNA1A | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100801476; called by muse, mutect2, varscan2
- CACNA1B | c.874T>C p.F292L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.266); catalogued as COSV53117480, COSV99495722; called by muse, mutect2, varscan2
- CACNA1B | c.2008T>C p.Y670H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99495724; called by muse, mutect2, varscan2
- CACNA1B | c.3288T>C p.S1096= | Splice Region (SNP) | VAF 8/117 reads (7%) | catalogued as COSV99495728; called by muse, mutect2
- CACNA1C | c.6170G>A p.S2057N (on ENST00000399634 / NM_001167625.1; = p.S1986N on NM_000719.7) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs755280013, COSV100216482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.4769G>A p.C1590Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.482); catalogued as rs747035819, COSV100661340; called by muse, mutect2, varscan2
- CACNA1I | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100359476; called by muse, mutect2, varscan2
- CACNA1I | c.5894T>C p.F1965S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100359479; called by muse, mutect2, varscan2
- CACNB2 | c.1838A>T p.D613V (on ENST00000324631 / NM_201596.3; = p.D558V on NM_000724.4) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV99993394; called by muse, mutect2, varscan2
- CACNG4 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs776495231, COSV100047416; called by muse, mutect2, varscan2
- CACYBP | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100871610, COSV62881371; called by muse, mutect2, varscan2
- CADM1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV59008787; called by muse, mutect2, varscan2
- CADM3 | c.322T>C p.Y108H (on ENST00000368125 / NM_001127173.3; = p.Y142H on NM_021189.5) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930276, COSV100930345; called by muse, mutect2, varscan2
- CAGE1 | c.1631A>G p.N544S (on ENST00000512086; = p.N408S on NM_205864.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99699439; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CANX | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.307); catalogued as COSV99910289; called by muse, mutect2, varscan2
- CAP1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs35749351; called by muse, mutect2, varscan2
- CAPN10 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99550015; called by muse, mutect2, varscan2
- CAPRIN1 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs1366549208, COSV100403608; called by muse, mutect2, varscan2
- CARD11 | c.767A>C p.D256A | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs749861673, COSV101210580; called by muse, mutect2, varscan2
- CARMIL3 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100549356; called by muse, mutect2, varscan2
- CARMIL3 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as COSV100549359; called by muse, mutect2, varscan2
- CARNMT1 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.289); catalogued as COSV100961659; called by muse, mutect2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs770159446; called by mutect2, varscan2
- CASK | c.2443A>C p.M815L (on ENST00000378163 / NM_001367721.1; = p.M810L on NM_003688.3) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100586880; called by muse, mutect2, varscan2
- CASP2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs898981516, COSV100130906; called by muse, mutect2, varscan2
- CASP6 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV99488598; called by muse, mutect2, varscan2
- CASP8 | c.1261T>C p.Y421H (on ENST00000432109 / NM_033355.3; = p.Y438H on NM_001228.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99629926; called by muse, mutect2, varscan2
- CASP8 | c.1380del p.K461Nfs*10 (on ENST00000432109 / NM_033355.3; = p.K478Nfs*10 on NM_001228.4) | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | catalogued as COSV51859087; called by mutect2, pindel, varscan2
- CASR | c.2872C>G p.P958A (on ENST00000490131; = p.P1035A on NM_000388.4) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99948578; called by muse, mutect2, varscan2
- CBLL2 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100081490; called by muse, mutect2
- CBX6 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV99328007; called by muse, mutect2, varscan2
- CC2D1A | c.2638T>C p.Y880H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99582794; called by muse, mutect2
- CC2D2A | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV101052683; called by mutect2, varscan2
- CC2D2B | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV100729323; called by muse, mutect2, varscan2
- CCDC141 | c.3045G>T p.Q1015H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as COSV99836355; called by muse, mutect2, varscan2
- CCDC151 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100710459; called by muse, mutect2, varscan2
- CCDC151 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.88); catalogued as COSV99371320; called by muse, mutect2, varscan2
- CCDC151 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV99371327; called by muse, mutect2, varscan2
- CCDC180 | c.261-1G>T p.X87_splice | Splice Site (SNP) | VAF 15/213 reads (7%) | catalogued as COSV100826605; called by muse, mutect2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC185 | c.1262A>G p.D421G | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100838762; called by muse, mutect2, varscan2
- CCDC191 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs761565825, COSV55670186; called by muse, mutect2, varscan2
- CCDC32 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs369168610; called by muse, mutect2, varscan2
- CCDC66 | c.2530T>A p.S844T (on ENST00000394672 / NM_001353147.1; = p.S810T on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV100413766; called by muse, mutect2, varscan2
- CCDC78 | c.560+1G>A p.X187_splice | Splice Site (SNP) | VAF 34/158 reads (22%) | catalogued as COSV52404368, COSV99284602, COSV99285005; called by muse, mutect2, varscan2
- CCDC92 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769500480, COSV99435306; called by muse, mutect2, varscan2
- CCIN | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100631659; called by muse, mutect2
- CCNA1 | c.641A>C p.E214A | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99714395; called by muse, mutect2, varscan2
- CCND2 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as COSV99714057; called by muse, mutect2, varscan2
- CCND2 | c.591C>G p.Y197* | Nonsense Mutation (SNP) | VAF 52/269 reads (19%) | catalogued as COSV54223469, COSV99714058; called by muse, mutect2, varscan2
- CCR2 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99432135; called by muse, mutect2, varscan2
- CCRL2 | c.34T>A p.Y12N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644983; called by muse, varscan2
- CCT4 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs769218948, COSV66702234; called by muse, mutect2, varscan2
- CCZ1 | c.698+2T>C p.X233_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100382722; called by muse, mutect2, varscan2
- CCZ1B | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as COSV100367782; called by muse, mutect2, varscan2
- CD200R1 | c.433T>C p.Y145H (on ENST00000471858 / NM_170780.3; = p.Y168H on NM_138806.4) | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99866858; called by muse, varscan2
- CD226 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99710864; called by muse, mutect2, varscan2
- CD244 | c.925T>C p.S309P (on ENST00000368033 / NM_001166663.2; = p.S304P on NM_016382.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV100458309; called by muse, mutect2, varscan2
- CD2BP2 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs751813994, COSV59769105, COSV59769147; called by muse, mutect2, varscan2
- CD34 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV100178212; called by muse, mutect2, varscan2
- CDAN1 | c.1924T>C p.F642L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100661195; called by muse, mutect2, varscan2
- CDC25C | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV100086563; called by muse, mutect2, varscan2
- CDC27 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs746492486, COSV99294137; called by muse, mutect2, varscan2
- CDC42EP4 | c.706del p.E236Rfs*146 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs1328494613; called by mutect2, pindel, varscan2
- CDCA2 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs765086906, COSV100398771; called by muse, mutect2, varscan2
- CDCA4 | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV100288132; called by muse, mutect2, varscan2
- CDCA7L | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs775772395, COSV100650986; called by muse, mutect2, varscan2
- CDH10 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775638474, COSV100050438, COSV52575246; called by muse, mutect2, varscan2
- CDH12 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs763180534, COSV66389256; called by muse, mutect2, varscan2
- CDH13 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV99223473; called by muse, mutect2, varscan2
- CDH18 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs771811447, COSV99932743; called by muse, mutect2, varscan2
- CDH22 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100952770; called by muse, mutect2, varscan2
- CDH24 | c.664_666del p.E222del | In Frame Del (DEL) | VAF 38/131 reads (29%) | catalogued as rs758825870; called by pindel, varscan2
- CDH6 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99418310; called by muse, mutect2, varscan2
- CDH6 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99418311; called by muse, mutect2, varscan2
- CDK12 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70999863; called by muse, mutect2, varscan2
- CDON | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99700823; called by muse, mutect2, varscan2
- CDR2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99193488; called by muse, mutect2, varscan2
- CDS1 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99880435; called by muse, mutect2, varscan2
- CDYL | c.1283+1G>A p.X428_splice (on ENST00000328908 / NM_001368125.1; = p.X374_splice on NM_004824.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100188881; called by muse, mutect2, varscan2
- CEACAM18 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV101140221; called by muse, mutect2, varscan2
- CECR2 | c.2401A>G p.T801A (on ENST00000342247 / NM_001290047.2; = p.T618A on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs188173829, COSV99377273; called by mutect2, varscan2
- CELA3A | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV51581829; called by muse, mutect2, varscan2
- CELSR1 | c.5911A>G p.S1971G | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99417162; called by muse, mutect2, varscan2
- CELSR1 | c.5302C>T p.R1768W | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs765032369, COSV53096658; called by muse, mutect2, varscan2
- CELSR1 | c.3398A>G p.D1133G | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99417171; called by muse, mutect2
- CELSR1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV53094449; called by muse, mutect2, varscan2
- CELSR2 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV99603255; called by muse, mutect2, varscan2
- CELSR3 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99372851; called by muse, mutect2, varscan2
- CEMIP | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs200436734, COSV99586276; called by muse, mutect2, varscan2
- CEMIP | c.3128A>G p.Y1043C | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99586277; called by muse, mutect2, varscan2
- CENPE | c.7321G>A p.V2441I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99477227; called by muse, mutect2, varscan2
- CENPS-CORT | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV100471598; called by muse, mutect2, varscan2
- CENPU | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99859786; called by muse, mutect2, varscan2
- CEP164 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs747025136, COSV99632723; called by muse, varscan2
- CEP164 | c.3844C>A p.L1282M | Missense Mutation (SNP) | VAF 111/400 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99632727; called by muse, varscan2
- CEP170 | c.2954G>T p.R985M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100316612, COSV100317759, COSV60509960; called by muse, mutect2, varscan2
- CEP192 | c.5663G>A p.G1888D | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs776859016, COSV100380764; called by muse, mutect2, varscan2
- CEP250 | c.6896C>T p.T2299I | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100698784; called by muse, mutect2, varscan2
- CEP57 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1394014717, COSV100334608; called by muse, mutect2, varscan2
- CEP76 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.406); catalogued as COSV100042640; called by muse, mutect2, varscan2
- CFAP221 | c.1906T>A p.S636T | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV99732061; called by muse, mutect2, varscan2
- CFAP54 | c.6084T>C p.G2028= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100733009; called by muse, mutect2, varscan2
- CFAP69 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201312556, COSV100289889; called by muse, mutect2, varscan2
- CFAP70 | c.1560T>A p.N520K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100160270; called by muse, mutect2, varscan2
- CFHR5 | c.575T>C p.F192S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99888170, COSV99888374; called by muse, mutect2, varscan2
- CHAC1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1430982981, COSV71436038, COSV71436288; called by muse, mutect2, varscan2
- CHCHD2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs200784526, COSV68170030; called by muse, mutect2, varscan2
- CHD1L | c.2420A>C p.D807A | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100787362; called by muse, mutect2, varscan2
- CHD2 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101244839; called by muse, mutect2, varscan2
- CHD4 | c.5691+2T>C p.X1897_splice (on ENST00000357008 / NM_001363606.2; = p.X1907_splice on NM_001273.5) | Splice Site (SNP) | VAF 62/299 reads (21%) | catalogued as COSV100444734; called by muse, mutect2, varscan2
- CHD5 | c.4957C>G p.L1653V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV99312784; called by muse, mutect2, varscan2
- CHD6 | c.4008-1G>C p.X1336_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58561654, COSV58563027; called by muse, mutect2, varscan2
- CHD7 | c.8803G>A p.E2935K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as rs745944842, CM090042, COSV71115041; called by muse, mutect2, varscan2
- CHD9 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101271962; called by muse, mutect2, varscan2
- CHD9 | c.5582G>C p.R1861T | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.307); catalogued as COSV99528814; called by muse, varscan2
- CHD9 | c.5649G>C p.L1883F | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99528788; called by muse, varscan2
- CHFR | c.786A>T p.G262= (on ENST00000432561 / NM_001161345.1; = p.G221= on NM_018223.2) | Splice Region (SNP) | VAF 30/155 reads (19%) | catalogued as COSV99905049; called by muse, mutect2, varscan2
- CHMP2B | c.432T>A p.D144E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV99773245; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 37/88 reads (42%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRAC1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as COSV55269774; called by muse, mutect2, varscan2
- CHRD | c.2516T>C p.V839A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs1376026705, COSV99200263; called by muse, mutect2, varscan2
- CHRNA10 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.591); catalogued as COSV99167131; called by muse, mutect2
- CHRNA2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs766076722, COSV99531962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA2 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV99531968; called by muse, mutect2, varscan2
- CHRNA9 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs757109316, COSV100038850; called by muse, mutect2, varscan2
- CHRND | c.236T>C p.I79T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs121909509, CM081555, COSV99285574; called by muse, mutect2, varscan2
- CHRND | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99285575; called by muse, mutect2, varscan2
- CHRNG | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV99285576; called by muse, mutect2, varscan2
- CHRNG | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV101263901; called by muse, mutect2, varscan2
- CHST5 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147059773; called by muse, mutect2, varscan2
- CHST7 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.64); catalogued as COSV52099964; called by muse, mutect2
- CIAO3 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs143166023; called by muse, mutect2, varscan2
- CIITA | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs745911038, COSV60854594; called by muse, mutect2, varscan2
- CILP | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.803); catalogued as rs769904740, COSV56025127; called by muse, mutect2, varscan2
- CILP2 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99364415; called by muse, mutect2
- CKAP5 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100370523; called by muse, mutect2
- CLASP2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs778183956, COSV56279291; called by muse, mutect2, varscan2
- CLC | c.152T>A p.V51D | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99695554; called by muse, mutect2, varscan2
- CLCC1 | c.1348G>A p.A450T (on ENST00000356970 / NM_001377464.1; = p.A400T on NM_015127.5) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs755037232, COSV100206168; called by muse, mutect2, varscan2
- CLDN11 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99290938; called by muse, mutect2, varscan2
- CLEC3A | c.493C>T p.R165C (on ENST00000651443; = p.R156C on NM_005752.6) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs770103147, COSV100222103, COSV55221365; called by muse, mutect2, varscan2
- CLEC4F | c.1738A>G p.T580A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99713598; called by muse, mutect2, varscan2
- CLEC4F | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV99713599; called by muse, mutect2, varscan2
- CLEC4G | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762166801, COSV100183599; called by muse, mutect2, varscan2
- CLIP2 | c.2737C>T p.R913W | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782695241, COSV99791148; called by muse, mutect2, varscan2
- CLMN | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV54182751, COSV54186592; called by muse, mutect2, varscan2
- CLPB | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99577733; called by muse, mutect2, varscan2
- CLPX | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100269327; called by muse, mutect2
- CLPX | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100269331; called by muse, mutect2, varscan2
- CLUAP1 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100489545; called by muse, mutect2, varscan2
- CLUH | c.482T>A p.V161D (on ENST00000435359; = p.V199D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV101425652; called by muse, mutect2, varscan2
- CLUL1 | c.1395C>A p.T465= | Splice Region (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100093687; called by muse, mutect2, varscan2
- CLVS2 | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99252292; called by muse, mutect2, varscan2
- CMTM1 | c.180dup p.I61Yfs*21 (on ENST00000457188 / NM_181269.3; = p.I178Yfs*21 on NM_052999.4) | Frame Shift Ins (INS) | VAF 37/169 reads (22%) | catalogued as rs773521289; called by mutect2, varscan2
- CMYA5 | c.8539A>G p.T2847A | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1261857689, COSV101483936; called by muse, mutect2, varscan2
- CMYA5 | c.11189A>G p.N3730S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV101483937; called by muse, mutect2, varscan2
- CNBD2 | c.1321A>T p.I441F (on ENST00000373973 / NM_001365709.1; = p.I437F on NM_080834.4) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100839054; called by muse, mutect2, varscan2
- CNDP1 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100722217; called by muse, mutect2, varscan2
- CNGA3 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344704591, COSV99736236; called by muse, mutect2, varscan2
- CNKSR3 | c.219T>C p.N73= | Splice Region (SNP) | VAF 35/123 reads (28%) | catalogued as COSV72161681; called by muse, mutect2, varscan2
- CNNM2 | c.568T>C p.Y190H | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.355); catalogued as COSV100881661; called by muse, mutect2, varscan2
- CNOT2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV57502658; called by muse, varscan2
- CNOT2 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99972454; called by muse, mutect2, varscan2
- CNOT8 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV99597125; called by muse, mutect2, varscan2
- CNPY4 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53543256; called by muse, mutect2, varscan2
- CNTN5 | c.2494T>C p.S832P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.783); catalogued as COSV99674019; called by muse, mutect2, varscan2
- CNTRL | c.1604A>T p.D535V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV99441409; called by muse, mutect2, varscan2
- COG7 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100207406; called by muse, mutect2
- COG8 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs995346978, COSV99846461; called by muse, mutect2
- COL14A1 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV99918320; called by muse, mutect2, varscan2
- COL14A1 | c.3775T>C p.F1259L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99918324; called by muse, mutect2
- COL15A1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs752948252, COSV100897882, COSV66644948; called by muse, mutect2, varscan2
- COL16A1 | c.1398G>A p.P466= | Splice Region (SNP) | VAF 21/76 reads (28%) | catalogued as rs569873845, COSV99593732, COSV99595302; called by muse, mutect2, varscan2
- COL16A1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99593736; called by muse, mutect2, varscan2
- COL19A1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 34/136 reads (25%) | catalogued as rs759890824, COSV59574999; called by muse, mutect2, varscan2
- COL3A1 | c.3632A>G p.E1211G | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as COSV100482636; called by muse, mutect2, varscan2
- COL5A1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV100879627; called by muse, mutect2, varscan2
- COL5A3 | c.3143del p.P1048Lfs*96 | Frame Shift Del (DEL) | VAF 40/182 reads (22%) | catalogued as rs771976753; called by mutect2, pindel, varscan2
- COL6A2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as rs755822013, COSV56015773; called by muse, mutect2, varscan2
- COL6A2 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs145381639, COSV99385210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4626dup p.G1543Rfs*33 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | catalogued as rs746783819; called by mutect2, varscan2
- COL6A6 | c.6416A>G p.H2139R | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100649960; called by muse, mutect2, varscan2
- COLGALT2 | c.1452T>A p.N484K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.314); catalogued as COSV100730472; called by muse, mutect2, varscan2
- COPB2 | c.2341A>G p.N781D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as rs1235691076, COSV100168985; called by muse, mutect2, varscan2
- COPB2 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV100300523; called by muse, mutect2, varscan2
- COPS3 | c.1207T>C p.F403L | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV99253513; called by muse, mutect2, varscan2
- COPS4 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018410; called by muse, mutect2
- CORIN | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903115; called by muse, mutect2, varscan2
- CORO1B | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100396287; called by muse, mutect2, varscan2
- CPA2 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs1169979648, COSV99743827; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPN2 | c.701del p.P234Lfs*10 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as COSV100103034; called by mutect2, pindel, varscan2
- CPSF2 | c.378A>G p.I126M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100102642; called by muse, mutect2
- CPSF3 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV99432550; called by muse, mutect2, varscan2
- CPSF3 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV99432554; called by muse, mutect2, varscan2
- CPT1C | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1026684162, COSV54918564, COSV54920916; called by muse, mutect2, varscan2
- CPXM1 | c.1306A>G p.N436D | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101013690; called by muse, mutect2, varscan2
- CPXM2 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs781558861, COSV53869307; called by muse, mutect2, varscan2
- CRACR2B | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV100351969; called by muse, mutect2, varscan2
- CRB2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs571013901, COSV63502278; called by muse, mutect2, varscan2
- CREB3L1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs376081099, COSV99914872; called by muse, mutect2, varscan2
- CREB3L3 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 52/216 reads (24%) | catalogued as rs753953218, COSV99313944; called by muse, mutect2, varscan2
- CREB5 | c.1094G>A p.R365H (on ENST00000357727 / NM_182898.4; = p.R358H on NM_004904.3) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV63225661; called by muse, mutect2, varscan2
- CRISPLD2 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs187741570, COSV99295463; called by muse, mutect2, varscan2
- CRK | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 61/204 reads (30%) | catalogued as COSV100315549; called by muse, mutect2, varscan2
- CRLF1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101134949; called by muse, mutect2, varscan2
- CROCC | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs757236753, COSV100978091; called by muse, mutect2, varscan2
- CROCC | c.1426A>G p.T476A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as rs1251665240, COSV100978092; called by mutect2, varscan2
- CROCC | c.2826G>T p.E942D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100978093; called by muse, mutect2, varscan2
- CROCC | c.3520C>T p.R1174W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1369378524, COSV100978029; called by muse, mutect2, varscan2
- CROCC | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs754225369, COSV100978094; called by muse, mutect2, varscan2
- CRTAC1 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085143; called by muse, mutect2, varscan2
- CRYAA | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs776884812, COSV99374830; called by muse, mutect2, varscan2
- CRYBA1 | c.272_274del p.G91del | In Frame Del (DEL) | VAF 24/129 reads (19%) | catalogued as rs1064797219; called by pindel, varscan2
- CSF2RB | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99453373; called by muse, varscan2
- CSGALNACT1 | c.635-2A>G p.X212_splice | Splice Site (SNP) | VAF 51/205 reads (25%) | catalogued as COSV100174612; called by muse, mutect2, varscan2
- CSNK1A1L | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV65790011; called by muse, mutect2, varscan2
- CSNK2A2 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99345205; called by muse, mutect2, varscan2
- CSPP1 | c.3229G>A p.A1077T (on ENST00000676605; = p.A1036T on NM_024790.6) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs750449850, COSV99138098; called by muse, mutect2, varscan2
- CTC1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs191350236, COSV100236201; called by muse, mutect2, varscan2
- CTCF | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV50547213; called by muse, mutect2, varscan2
- CTLA4 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99865121; called by muse, mutect2, varscan2
- CTNNB1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs1267755116, COSV62691474; called by muse, mutect2, varscan2
- CTSC | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910536; called by muse, mutect2, varscan2
- CUL2 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV101039059; called by muse, mutect2, varscan2
- CUL7 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99538071; called by muse, mutect2, varscan2
- CUX1 | c.1027G>A p.E343K (on ENST00000292535 / NM_181552.4; = p.E354K on NM_001913.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV52909651; called by muse, mutect2, varscan2
- CUX1 | c.1856A>G p.N619S | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99470779; called by muse, mutect2, varscan2
- CUX1 | c.1609A>G p.S537G (on ENST00000437600 / NM_181500.4; = p.S539G on NM_001913.5) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV99474849; called by muse, mutect2
- CXCL17 | c.359A>G p.*120Wext*3 | Nonstop Mutation (SNP) | VAF 93/426 reads (22%) | catalogued as COSV99733901; called by muse, mutect2, varscan2
- CXXC1 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99495690; called by muse, mutect2, varscan2
- CYFIP1 | c.3715G>A p.V1239M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs920182114, COSV100487885; called by muse, mutect2, varscan2
- CYLD | c.1598T>C p.F533S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100282252; called by muse, mutect2, varscan2
- CYP19A1 | c.1498T>C p.C500R | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); catalogued as COSV99547426; called by muse, mutect2, varscan2
- CYP1A2 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100673863, COSV59659597; called by muse, mutect2, varscan2
- CYP2A13 | c.464T>C p.F155S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV100386670, COSV57837436; called by muse, mutect2, varscan2
- CYP46A1 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs754138869, COSV99952488; called by muse, mutect2, varscan2
- CYP4F11 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV99930682; called by muse, mutect2, varscan2
- CYP4F8 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100358039; called by muse, mutect2, varscan2
- CYP7A1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs766893445, COSV56962199; ClinVar: uncertain significance; called by muse, mutect2
- D2HGDH | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100344236; called by muse, mutect2, varscan2
- DAAM1 | c.1447A>G p.M483V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100658213; called by muse, mutect2
- DAB1 | c.1370C>T p.P457L (on ENST00000371231; = p.P424L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs768694523, COSV64695642; called by muse, mutect2, varscan2
- DACH1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100497726; called by muse, mutect2, varscan2
- DAPK1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100801239; called by muse, varscan2
- DBF4 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.091); catalogued as rs1451611933, COSV55995732, COSV99719195; called by muse, mutect2, varscan2
- DBN1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 124/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99445675; called by muse, varscan2
- DBNDD2 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373093739; called by muse, mutect2, varscan2
- DBP | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV99709213; called by muse, mutect2, varscan2
- DBX1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs757464120, COSV99910130; called by muse, mutect2, varscan2
- DCAF15 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV99585853; called by muse, mutect2, varscan2
- DCAF16 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV101200398; called by muse, mutect2, varscan2
- DCAF4 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 120/577 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100610936; called by muse, mutect2, varscan2
- DCAF4L1 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100295587; called by muse, mutect2, varscan2
- DCAF5 | c.2492A>G p.N831S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as rs1482605832, COSV100432291; called by muse, mutect2, varscan2
- DCBLD2 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV100471617; called by muse, mutect2, varscan2
- DCK | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV104378720; called by muse, mutect2
- DCLRE1A | c.1032dup p.K345* | Frame Shift Ins (INS) | VAF 26/136 reads (19%) | catalogued as rs751315517; called by mutect2, varscan2
- DCP1A | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99587855; called by muse, mutect2, varscan2
- DDO | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100927821; called by muse, mutect2, varscan2
- DDX10 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as rs777793234, COSV59437356; called by muse, mutect2, varscan2
- DDX10 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs368051511; called by muse, mutect2, varscan2
- DDX11 | c.2437G>A p.A813T (on ENST00000545668 / NM_152438.2; = p.A763T on NM_004399.3) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as COSV99299139; called by muse, mutect2, varscan2
- DDX21 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs771949249, COSV62556701; called by muse, mutect2, varscan2
- DDX46 | c.1954+2T>C p.X652_splice | Splice Site (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100844855, COSV62798947; called by muse, mutect2
- DDX60 | c.3620A>G p.H1207R | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1438378214, COSV101190299; called by muse, mutect2, varscan2
- DDX60 | c.2102A>T p.Y701F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV101190300; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs757771764; called by mutect2, varscan2
- DENND2B | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV100567242, COSV58204071; called by muse, mutect2, varscan2
- DENND4A | c.2992A>G p.T998A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101475276; called by muse, mutect2
- DENND4B | c.2390A>G p.Y797C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100768498; called by muse, mutect2
- DENND4C | c.966dup p.E323* | Frame Shift Ins (INS) | VAF 25/130 reads (19%) | catalogued as rs1428440687; called by mutect2, varscan2
- DENND4C | c.3610A>G p.T1204A (on ENST00000434457 / NM_001330640.2; = p.T1155A on NM_017925.7) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs142943763; called by muse, mutect2, varscan2
- DENND5B | c.1846A>T p.T616S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100171064; called by muse, varscan2
- DEPDC1B | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs150780889; called by muse, mutect2, varscan2
- DEPDC5 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1387253051, COSV99834616; called by muse, mutect2, varscan2
- DGKD | c.3593T>C p.I1198T (on ENST00000264057 / NM_152879.3; = p.I1154T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99895671; called by muse, mutect2
- DGKG | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775498146, COSV53968480; called by muse, mutect2, varscan2
- DGKK | c.2819A>G p.Y940C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052911, COSV65707377; called by muse, mutect2, varscan2
- DHH | c.415T>C p.S139P | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV99908769; called by muse, mutect2, varscan2
- DHRS7C | c.538A>G p.I180V (on ENST00000330255 / NM_001220493.2; = p.I179V on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV100364574; called by muse, mutect2, varscan2
- DHX16 | c.667-2A>T p.X223_splice | Splice Site (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100905140; called by muse, mutect2, varscan2
- DHX16 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100906052; called by muse, mutect2, varscan2
- DHX30 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs138729543; called by muse, mutect2, varscan2
- DHX37 | c.3091C>T p.R1031W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs376946837; called by muse, mutect2, varscan2
- DHX58 | c.710T>C p.M237T | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99288073; called by muse, mutect2
- DIABLO | c.460C>T p.R154W (on ENST00000443649 / NM_001278303.1; = p.R227W on NM_019887.6) | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs371241484; called by muse, mutect2, varscan2
- DIAPH2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61271506, COSV61284150; called by muse, mutect2, varscan2
- DICER1 | c.5515C>T p.R1839W | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1447120867, COSV58616133; ClinVar: uncertain significance; called by muse, mutect2
- DICER1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100601843; called by muse, mutect2, varscan2
- DIDO1 | c.2608A>G p.K870E | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99825047; called by muse, mutect2, varscan2
- DIP2C | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV99790470; called by muse, mutect2, varscan2
- DIPK1B | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766943583, COSV100765442; called by muse, mutect2, varscan2
- DIS3L2 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV99805644; called by muse, mutect2, varscan2
- DIS3L2 | c.1835dup p.P613Afs*8 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs1316690885; called by mutect2, pindel
- DLAT | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV99734487; called by muse, mutect2, varscan2
- DLG1 | c.2273G>C p.R758T (on ENST00000419354 / NM_001290983.1; = p.R780T on NM_004087.2) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100014841; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- DLGAP3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52393794; called by muse, mutect2, varscan2
- DLGAP3 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99332303; called by muse, mutect2
- DLL1 | c.412+2T>C p.X138_splice | Splice Site (SNP) | VAF 66/232 reads (28%) | catalogued as COSV100815957; called by muse, mutect2, varscan2
- DLX5 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99756281; called by muse, mutect2, varscan2
- DMD | c.6291G>A p.G2097= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100818546; called by muse, mutect2, varscan2
- DNAAF2 | c.2150T>C p.L717P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100023869; called by muse, varscan2
- DNAAF4 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV100336628; called by muse, mutect2, varscan2
- DNAH1 | c.5639C>T p.T1880M | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1191126652, COSV101324962; called by muse, mutect2, varscan2
- DNAH1 | c.8014G>A p.A2672T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101324963; called by muse, varscan2
- DNAH1 | c.10015A>G p.T3339A | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV101324968; called by muse, mutect2, varscan2
- DNAH10 | c.4078G>A p.E1360K (on ENST00000409039; = p.E1299K on NM_207437.3) | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV101292074; called by muse, mutect2, varscan2
- DNAH10 | c.5447T>C p.F1816S (on ENST00000409039; = p.F1755S on NM_207437.3) | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101292075; called by muse, mutect2, varscan2
- DNAH11 | c.13112C>T p.P4371L | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238638659, COSV60945958; called by muse, mutect2
- DNAH17 | c.12200A>G p.Y4067C | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV101101660; called by muse, mutect2, varscan2
- DNAH17 | c.5975A>G p.E1992G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101101662; called by muse, mutect2, varscan2
- DNAH17 | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV101101663; called by muse, mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAH8 | c.11074T>C p.Y3692H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100543747; called by muse, mutect2, varscan2
- DNAH9 | c.9305A>G p.E3102G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV99304648; called by muse, mutect2, varscan2
- DNAJB12 | c.385A>G p.T129A (on ENST00000338820; = p.T95A on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/578 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs749872715, COSV100123691; called by muse, mutect2, varscan2
- DNAJB13 | c.687C>G p.N229K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100334449; called by muse, mutect2, varscan2
- DNAJC1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100977993; called by muse, mutect2, varscan2
- DNAJC13 | c.3163T>C p.C1055R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99606805; called by muse, mutect2, varscan2
- DNAJC5G | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); catalogued as rs192714047, COSV99940506; called by muse, mutect2, varscan2
- DNASE1L2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100065469; called by muse, mutect2, varscan2
- DNM2 | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100116906; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs1360524239, COSV101455464; called by muse, mutect2, varscan2
- DOCK7 | c.4490C>T p.T1497M (on ENST00000635253 / NM_001367561.1; = p.T1466M on NM_033407.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.386); catalogued as rs200226943, COSV99223350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK9 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.068); catalogued as rs1273714418, COSV100238253; called by muse, mutect2
- DOK6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV101234313; called by muse, mutect2
- DONSON | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.48); catalogued as COSV99277192; called by muse, mutect2, varscan2
- DOP1A | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99381191; called by muse, mutect2, varscan2
- DPEP3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV99262596; called by muse, mutect2, varscan2
- DPF1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.604); catalogued as rs888692243, COSV100831433; called by muse, mutect2, varscan2
- DPF2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99361406; called by muse, mutect2, varscan2
- DPP4 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV100858729; called by muse, mutect2, varscan2
- DPY19L2 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100116588; called by muse, mutect2, varscan2
- DPYSL3 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100574943; called by muse, mutect2, varscan2
- DPYSL4 | c.1472T>A p.I491N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.209); catalogued as COSV100061998; called by muse, mutect2, varscan2
- DRD2 | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100669364; called by muse, mutect2, varscan2
- DSCAM | c.5690A>G p.D1897G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as rs1293990384, COSV101259357; called by muse, mutect2, varscan2
- DSCAM | c.4361A>G p.Q1454R | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.988); catalogued as COSV101259358; called by muse, mutect2, varscan2
- DSG1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs140838956; called by muse, mutect2, varscan2
- DSG4 | c.2141T>C p.I714T | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV100355500; called by muse, mutect2
- DSP | c.8378T>C p.M2793T | Missense Mutation (SNP) | VAF 103/478 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1421957071, COSV100672897; called by muse, mutect2, varscan2
- DSP | c.8576C>G p.S2859C | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs989922991, COSV100672898; called by muse, mutect2, varscan2
- DST | c.18979G>A p.A6327T (on ENST00000361203 / NM_001374722.1; = p.A4024T on NM_015548.5) | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as COSV99752385; called by muse, mutect2, varscan2
- DST | c.8605A>G p.N2869D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as COSV99752387; called by muse, mutect2, varscan2
- DST | c.7534A>G p.T2512A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99752389; called by muse, mutect2, varscan2
- DST | c.3040T>A p.S1014T (on ENST00000361203 / NM_001374722.1; = p.S688T on NM_001723.6) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99752394; called by muse, mutect2, varscan2
- DUOX2 | c.1271A>G p.D424G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985552458, COSV101199609; called by muse, mutect2, varscan2
- DUOXA1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746258066, COSV99972929; called by muse, mutect2, varscan2
- DVL1 | c.1220C>T p.A407V (on ENST00000378888 / NM_001330311.2; = p.A382V on NM_004421.3) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.107); catalogued as rs1489820473, COSV100229321; called by muse, mutect2, varscan2
- DVL1 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV101127326; called by muse, mutect2, varscan2
- DVL3 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV100493555; called by muse, mutect2, varscan2
- DYNLL2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV101651049; called by muse, mutect2, varscan2
- DYRK2 | c.820C>T p.R274W (on ENST00000344096 / NM_006482.3; = p.R201W on NM_003583.4) | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201048832, COSV59847295; called by muse, mutect2, varscan2
- EBF1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100565383; called by muse, mutect2, varscan2
- EBF2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369154726; called by muse, mutect2, varscan2
- ECE1 | c.1952A>T p.N651I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV99941479; called by muse, mutect2, varscan2
- ECI1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs746451005, COSV57039552; called by muse, mutect2, varscan2
- EDAR | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99303201; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100200986, COSV61080937; called by muse, mutect2, varscan2
- EEF1AKNMT | c.560C>T p.A187V (on ENST00000361735 / NM_015935.5; = p.A101V on NM_014955.3) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs917531333, COSV100675792; called by muse, mutect2, varscan2
- EEPD1 | c.1567T>C p.S523P | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99631885; called by muse, mutect2
- EFCAB13 | c.1085del p.N362Ifs*5 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as rs1461678920; called by mutect2, pindel, varscan2
- EFHB | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.396); catalogued as COSV55547870; called by muse, mutect2
- EFNA1 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310240; called by muse, mutect2, varscan2
- EFNB3 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99872618; called by muse, mutect2, varscan2
- EGLN2 | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV58280198; called by muse, mutect2, varscan2
- EGR2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99654017; called by muse, mutect2, varscan2
- EHBP1 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.345); catalogued as COSV99860267; called by muse, mutect2, varscan2
- EHBP1L1 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499725; called by muse, mutect2, varscan2
- EHD1 | c.1181T>C p.M394T | Missense Mutation (SNP) | VAF 120/461 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100276893; called by muse, mutect2, varscan2
- EHD3 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs778192677, COSV100434641; called by muse, mutect2, varscan2
- EHMT1 | c.2743T>C p.F915L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.456); catalogued as COSV101509600; called by muse, varscan2
- EHMT1 | c.2849A>G p.N950S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV101509601; called by muse, varscan2
- EIF2B2 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99837635; called by muse, varscan2
- EIF2B2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs749995021, COSV99837636; called by muse, varscan2
- EIF4E | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99794683; called by muse, mutect2, varscan2
- EIF4G1 | c.632C>T p.T211M (on ENST00000346169 / NM_198241.3; = p.T15M on NM_004953.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs762038648, COSV100071560; called by muse, mutect2, varscan2
- EIF5B | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1324680978, COSV99176879; called by muse, mutect2, varscan2
- ELAC1 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV99494803; called by muse, mutect2, varscan2
- ELAC2 | c.1219-1G>A p.X407_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100568380; called by muse, mutect2, varscan2
- ELK3 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV57388414, COSV99957534; called by muse, mutect2
- ELMO2 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99281497; called by muse, varscan2
- ELOC | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99513857; called by muse, mutect2, varscan2
- ELOVL3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100892757; called by muse, mutect2, varscan2
- ELSPBP1 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100353531; called by muse, mutect2, varscan2
- EML1 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV99214642; called by muse, mutect2, varscan2
- EML5 | c.4992C>T p.G1664= (on ENST00000380664; = p.G1672= on NM_183387.3) | Splice Region (SNP) | VAF 52/204 reads (25%) | catalogued as COSV100715177; called by muse, mutect2, varscan2
- EMP1 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs774431121, COSV56998625; called by muse, mutect2, varscan2
- EMSY | c.264C>A p.S88R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100595488; called by muse, mutect2, varscan2
- EMSY | c.3899A>G p.Q1300R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV100595492; called by muse, mutect2, varscan2
- EN1 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV54630275, COSV99727023; called by muse, mutect2, varscan2
- ENO3 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs1253948847, COSV52777129, COSV99236260; called by muse, mutect2, varscan2
- ENPP3 | c.2600A>G p.Y867C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100716835; called by muse, mutect2, varscan2
- ENPP5 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100040344; called by muse, mutect2, varscan2
- ENTPD7 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100978358; called by muse, mutect2
- EPAS1 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.46); catalogued as rs1232746100, COSV99762996; called by muse, mutect2, varscan2
- EPB41L3 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100548307; called by muse, mutect2, varscan2
- EPB41L5 | c.1742A>G p.D581G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99758398; called by muse, varscan2
- EPC2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs780130752, COSV99309208; called by muse, varscan2
- EPDR1 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99554285; called by muse, mutect2, varscan2
- EPHA1 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV99313595; called by muse, mutect2, varscan2
- EPHA7 | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100993382; called by muse, mutect2
- EPHA8 | c.1550C>G p.S517* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99384398; called by muse, mutect2, varscan2
- EPHB2 | c.3017A>G p.D1006G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen benign (0); catalogued as rs777249772, COSV101006824; called by muse, mutect2
- EPHB3 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs980639494, COSV100382860, COSV100383095; called by muse, mutect2, varscan2
- EPHB4 | c.1775A>C p.D592A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100639424; called by muse, mutect2, varscan2
- EPHX4 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100952654; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 24/95 reads (25%) | catalogued as rs756461692; called by mutect2, varscan2
- EPS15 | c.104T>C p.L35S | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.51); catalogued as COSV100869052; called by muse, mutect2, varscan2
- EPS15L1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV50168689, COSV99932782; called by muse, mutect2, varscan2
- EPS8L1 | c.467A>G p.H156R (on ENST00000201647 / NM_133180.3; = p.H29R on NM_017729.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV99135798; called by muse, mutect2, varscan2
- EPS8L1 | c.947A>G p.Y316C (on ENST00000201647 / NM_133180.3; = p.Y189C on NM_017729.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV99135804; called by muse, mutect2
- ERBIN | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99396128; called by muse, mutect2, varscan2
- ERBIN | c.2492A>G p.Q831R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs143804809, COSV99396131; called by muse, mutect2, varscan2
- ERCC2 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs533062241, COSV101228824; called by muse, mutect2, varscan2
- ETF1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV100860058; called by muse, mutect2, varscan2
- ETFA | c.425A>C p.D142A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99144182; called by muse, mutect2, varscan2
- EVPL | c.3692T>C p.V1231A | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100044124; called by muse, mutect2, varscan2
- EXOC3 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as rs1413713815, COSV59267543; called by muse, mutect2, varscan2
- EXOC4 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54106118; called by muse, mutect2, varscan2
- EXOC6B | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as rs766170220, COSV55566619, COSV99723156; called by muse, mutect2, varscan2
- EXPH5 | c.5113A>G p.N1705D | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV99761125; called by muse, mutect2
- EXT2 | c.19T>C p.Y7H (on ENST00000343631; = p.Y40H on NM_000401.3) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100640530; called by muse, mutect2, varscan2
- EYA1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs200923204, CM085391, COSV58157220; called by muse, mutect2, varscan2
- F13B | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV66374125; called by muse, mutect2, varscan2
- F2R | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1235324522, COSV100058354; called by muse, mutect2, varscan2
- FABP1 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV99860800; called by muse, mutect2, varscan2
- FAM118A | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99343456; called by muse, mutect2, varscan2
- FAM120A | c.3247A>T p.N1083Y | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV99464747; called by muse, mutect2, varscan2
- FAM135B | c.2050T>C p.S684P | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99420429; called by muse, mutect2, varscan2
- FAM186B | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV99218186; called by muse, mutect2, varscan2
- FAM187B | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100219969; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 64/311 reads (21%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM204A | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100977415; called by muse, mutect2, varscan2
2,844 further variants in this file (1,908 protein-altering or splice-affecting, 864 silent, 72 other) are not listed here.
